Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7QX, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7QX-01A (Primary Tumor).

ICD-3
Astrocytoma, grade III 94013
Site: ^{CNS} Brain, supratentorial NOS C71.0
^{Path} Brain, NOS C71.9
9/27/13

Glial tumor of astrocytic differentiation
IDH1 R132H mutation present

Diagnosis:
anaplastic astrocytoma WHO grade III

Untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file 6acd2f52-b6e3-44ec-af5d-a06ede00ff15 (TCGA-S9-A7QX.C0F30532-18DA-4E77-A2CC-EFE67B476FA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).